Somatic mutation profile of tumor specimen MP2PRT-PATFLY-TMP1-A (aliquot MP2PRT-PATFLY-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PATFLY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.2 years (788 days).
Specimen MP2PRT-PATFLY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 39540d6c-2420-4f5f-82a4-eecb2bcdb221.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATFLY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATFLY-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ed79e57-e177-418e-b202-03aab518f7c4

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 2, Intron 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 157/367 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2132G>A p.G711E | Missense Mutation (SNP) | VAF 107/260 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59472159, COSV59472529; called by muse, mutect2, varscan2
- DACH2 | c.1199C>T p.S400F | Missense Mutation (SNP) | VAF 163/527 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.896); catalogued as rs763149898; called by muse, mutect2, varscan2
- DDR1 | c.1972C>T p.R658W (on ENST00000324771; = p.R621W on NM_001954.4) | Missense Mutation (SNP) | VAF 118/421 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780560727; called by muse, mutect2, varscan2
- DDX27 | c.1306C>T p.R436W | Missense Mutation (SNP) | VAF 193/466 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781427481, COSV65609543; called by muse, mutect2, varscan2
- IKZF1 | c.1531C>T p.R511* | Nonsense Mutation (SNP) | VAF 141/362 reads (39%) | catalogued as COSV58784180, COSV58788322; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 137/350 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRB10 | c.216del p.Q74Sfs*10 | Frame Shift Del (DEL) | VAF 205/607 reads (34%) | called by mutect2, pindel, varscan2
- NFATC2 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 22/719 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- TMEM260 | c.2006G>T p.R669I | Missense Mutation (SNP) | VAF 45/584 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); called by muse, mutect2
- ZNF804A | c.255G>T p.Q85H | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANO9 | c.432C>T p.D144= | Silent (SNP) | VAF 176/427 reads (41%) | catalogued as rs151302926; called by muse, mutect2, varscan2
- GNAS | c.1323C>T p.P441= | Silent (SNP) | VAF 122/1042 reads (12%) | catalogued as rs146744182; called by muse, varscan2
- MYB | c.1203+1317C>T | Intron (SNP) | VAF 106/395 reads (27%) | catalogued as rs373571701; called by muse, mutect2, varscan2
